CCDI case PBCHZU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a584172d-05bc-4187-b2b8-fe86e2d22b8a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (435 days).

Biospecimens (3 samples)
- Sample 0DSW98: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSW9G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSW9X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
